Somatic mutation profile of tumor specimen TCGA-B0-5400-01A (aliquot TCGA-B0-5400-01A-01D-1501-10) from TCGA case TCGA-B0-5400, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 59.7 years (21,819 days).
Specimen TCGA-B0-5400-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00474ab6-1f5c-49ce-972f-e36058f83a9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5400-11A (Solid Tissue Normal), aliquot TCGA-B0-5400-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ef1c130-d1b3-4cdc-a5c4-29248a7e66dd

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 10, Frame Shift Del 3, Nonsense Mutation 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.176C>G p.A59G | Missense Mutation (SNP) | VAF 31/291 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV55568979, COSV55604554, COSV55904854; called by muse, mutect2, varscan2
- ATP8A2 | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 60/552 reads (11%) | catalogued as COSV54945590; called by muse, varscan2
- CLIC6 | c.1751C>T p.T584M (on ENST00000360731 / NM_001317009.2; = p.T566M on NM_053277.3) | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs753768078, COSV62447444; called by muse, mutect2, varscan2
- CUL2 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV66078895; called by muse, mutect2, varscan2
- DLG4 | c.72C>A p.H24Q (on ENST00000399506 / NM_001321075.3; = p.H67Q on NM_001365.4) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.369); catalogued as COSV57237516; called by muse, mutect2
- DNAJC7 | c.368T>C p.L123P | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as COSV57268435; called by muse, mutect2, varscan2
- EPB41L4B | c.1730C>A p.P577H | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV65802576; called by muse, mutect2, varscan2
- GOT2 | c.1166A>G p.E389G | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV55331318; called by muse, mutect2, varscan2
- LILRB5 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV60256208; called by muse, mutect2, varscan2
- LIMA1 | c.305A>T p.D102V | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV57964868; called by muse, mutect2, varscan2
- LRRTM3 | c.1512C>A p.N504K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as rs1201446863, COSV63663687; called by muse, mutect2, varscan2
- MFSD6 | c.1630G>T p.G544* | Nonsense Mutation (SNP) | VAF 39/320 reads (12%) | catalogued as COSV55621947; called by muse, mutect2, varscan2
- NLRP9 | c.1759C>T p.H587Y | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV60461640; called by muse, mutect2, varscan2
- NRCAM | c.2812C>T p.P938S (on ENST00000379028 / NM_001371124.1; = p.P922S on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61034057; called by muse, mutect2, varscan2
- PIGN | c.623T>C p.L208S | Missense Mutation (SNP) | VAF 55/411 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62948558; called by muse, mutect2, varscan2
- SFXN4 | c.192C>G p.N64K | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57459761; called by muse, mutect2, varscan2
- SHC1 | c.616A>C p.T206P (on ENST00000368445 / NM_183001.5; = p.T96P on NM_003029.5) | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.423); catalogued as COSV63534712; called by muse, mutect2, varscan2
- SLC4A7 | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 99/720 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV104404076, COSV55396066; called by muse, mutect2, varscan2
- SNX25 | c.2327T>C p.L776P | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180575371, COSV53013109; called by muse, mutect2
- TAS2R46 | c.248C>A p.T83N | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as COSV67854415; called by muse, varscan2
- TENM1 | c.3680G>C p.S1227T | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100949942, COSV64429069; called by muse, mutect2, varscan2
- TTC17 | c.2749G>A p.V917M | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.374); catalogued as rs766156231, COSV50007381; called by muse, mutect2, varscan2
- DAPK1 | c.355_362del p.F119Tfs*4 | Frame Shift Del (DEL) | VAF 46/451 reads (10%) | called by mutect2, pindel
- PSD4 | c.1517del p.K506Rfs*13 | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- TRIM6 | c.724_737del p.Q242Gfs*8 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel
- ACP7 | c.705T>G p.G235= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV58698733; called by mutect2, varscan2
- ALAS1 | c.1713G>A p.R571= | Silent (SNP) | VAF 13/126 reads (10%) | catalogued as COSV59627453; called by muse, mutect2, varscan2
- CH25H | c.60G>A p.L20= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV64092279; called by muse, mutect2, varscan2
- FBXW7 | c.2022G>C p.R674= (on ENST00000281708 / NM_001349798.2; = p.R594= on NM_018315.5) | Silent (SNP) | VAF 38/339 reads (11%) | catalogued as COSV55906365; called by muse, mutect2, varscan2
- IWS1 | c.177C>A p.G59= | Silent (SNP) | VAF 25/201 reads (12%) | catalogued as COSV54867361; called by muse, mutect2, varscan2
- KRT32 | c.1152C>T p.D384= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1254374263, COSV56786223; called by muse, varscan2
- LRRC18 | c.414C>T p.T138= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as COSV53282868; called by muse, mutect2, varscan2
- OTUD3 | c.999A>G p.A333= | Silent (SNP) | VAF 42/383 reads (11%) | catalogued as COSV64295651; called by muse, mutect2
- SEMA3E | c.2238C>T p.P746= | Silent (SNP) | VAF 32/335 reads (10%) | catalogued as COSV57084993; called by muse, mutect2, varscan2
- TARBP1 | c.1386A>G p.P462= | Silent (SNP) | VAF 23/278 reads (8%) | catalogued as COSV50182005; called by muse, mutect2
- AQR | c.471+1052dup | Intron (INS) | VAF 3/21 reads (14%) | called by mutect2, pindel
- KMT2C | c.11670+1078del | Intron (DEL) | VAF 22/158 reads (14%) | called by mutect2, pindel, varscan2
